Somatic mutation profile of tumor specimen TCGA-TT-A6YN-01A (aliquot TCGA-TT-A6YN-01A-12D-A35I-08) from TCGA case TCGA-TT-A6YN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 37.2 years (13,605 days).
Specimen TCGA-TT-A6YN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be7fbdf6-a3fe-420a-be14-810ba322b1d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TT-A6YN-10A (Blood Derived Normal), aliquot TCGA-TT-A6YN-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd1b0cc7-ce95-4b07-a9c5-5e402cb4f81a

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCSK7 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429766974; called by muse, mutect2, varscan2
- SUN1 | c.452-2A>T p.X151_splice (on ENST00000405266 / NM_001367651.1; = p.X101_splice on NM_025154.6 and 13 other RefSeq transcripts) | Splice Site (SNP) | VAF 4/43 reads (9%) | catalogued as rs1206187476; called by muse, varscan2
- TPR | c.3068G>A p.R1023K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIPT1 | c.390G>A p.L130= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- PAPPA | c.3756G>A p.R1252= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- TUBE1 | c.798C>T p.L266= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as rs782713361; called by muse, mutect2, varscan2
- UBE3C | c.3213C>G p.L1071= | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
